Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8D7, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8D7-01A (Primary Tumor).

IC003

Thymoma, type B, malignant
8583/3

Thymus C379

7/26/13/14

Operative Procedure:

Mediastinal mass resection and sternotomy.

Pre-Operative Diagnosis:

As below.

Post-Operative Diagnosis:

As below.

Specimen Received:

A: Thymus \T\ mass

B: AP Window Lymph node

Final Pathologic Diagnosis:

A. Thymus, thymectomy:

Thymoma, WHO type B1.

Maximal tumor dimension - 9cm

Microscopic invasion of adjacent adipose tissue present.

The tumor is 1 mm away from the inked resection margin.

B. Lymph node, AP window, excision:

Negative for malignancy.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received are two specimen containers labeled with the patient's name

A. A is received fresh and subsequently placed in formalin and labeled "thymus." The specimen consists of a 120 gram, 12.5 x 11.5 x 3.0 cm portion of yellow lobulated fibrofatty tissue to include a 9.0 x 6.0 x 2.5 cm grossly encapsulated mass, having a homogenous somewhat fish flesh cut surface with hemorrhage noted. Distinct necrosis is not grossly identified. Interface of tumor to fat presents for the most part distinct with minimal lobulation.

Within the associated fatty tissues is a single lymph node candidate. Sections are submitted as follows:

- A1-4 tumor to include fat interface;
- A5 additional sections of unremarkable fat;
- A6 presumed lymph node.

B. Part B is received and additionally labeled "AP window node." The specimen consists of a single 2.0 cm in greatest dimension portion of multi lobulated tan-brown and yellow soft tissue, which is submitted in its entirety in B.

Microscopic Description:

A microscopic examination is performed.

Taken:

DOB:

Gender:

F

Race: Black

Dual/Synchronous Tumor		

Source: NCI Genomic Data Commons file 7d971826-3036-421a-87b5-5d9ccd9d4a18 (TCGA-X7-A8D7.5B872E6E-87FA-4BB7-8D8A-9E39FC8994B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).